Somatic mutation profile of tumor specimen TCGA-EE-A2M6-06A (aliquot TCGA-EE-A2M6-06A-12D-A197-08) from TCGA case TCGA-EE-A2M6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 64.4 years (23,507 days).
Specimen TCGA-EE-A2M6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5eba9530-5c2f-48b0-84dc-b851f0e26411.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2M6-10A (Blood Derived Normal), aliquot TCGA-EE-A2M6-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c744a1e-0209-45bc-8b8a-ab19a3f22379

The open-access MAF lists 649 somatic variants for this specimen: 436 protein-altering or splice-affecting, 190 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 391, Silent 190, Nonsense Mutation 27, Intron 12, Splice Site 10, Frame Shift Del 5, RNA 4, 3'Flank 4, 5'Flank 2, Splice Region 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAG3 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as rs1057517945, CM111933, COSV64842698; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 15/35 reads (43%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- DNAH5 | c.11907G>A p.W3969* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs1561122898, COSV54204150; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1613T>A p.L538Q | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52230012; called by muse, mutect2, varscan2
- ABCA10 | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs1462336954, COSV52230022; called by muse, mutect2, varscan2
- ABCA12 | c.2903G>A p.R968K (on ENST00000272895 / NM_173076.3; = p.R650K on NM_015657.3) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55976239; called by muse, mutect2, varscan2
- ABCG4 | c.647T>G p.V216G | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56645812; called by muse, mutect2
- ABTB2 | c.2524A>G p.K842E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as COSV54396183; called by muse, mutect2, varscan2
- ACADSB | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as rs745481903, COSV62551017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACBD3 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64731323; called by muse, mutect2, varscan2
- ACD | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | catalogued as COSV99537309; called by muse, varscan2
- ACD | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV99537313; called by muse, varscan2
- ACOX1 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143601596, COSV53136887; called by muse, mutect2, varscan2
- ACR | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs147392791; called by muse, mutect2, varscan2
- ACR | c.656T>A p.V219D | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99334281; called by muse, mutect2, varscan2
- ACSM5 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59369868, COSV59375137; called by muse, mutect2, varscan2
- ADAM2 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV55859555; called by muse, varscan2
- ADAM2 | c.1083T>A p.H361Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV55868648; called by muse, mutect2, varscan2
- ADAMTS13 | c.3955A>C p.T1319P | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.25); PolyPhen benign (0.123); catalogued as COSV52471862; called by muse, mutect2, varscan2
- ADAMTS14 | c.2263G>A p.V755M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV64606649; called by muse, mutect2
- ADAMTSL3 | c.4265C>T p.P1422L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs199806479, COSV54470395; called by muse, mutect2, varscan2
- ADCY8 | c.1835G>A p.R612K | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53928701, COSV53930321; called by muse, mutect2, varscan2
- AGTR2 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 59/63 reads (94%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs202224363, COSV64156312; called by muse, mutect2, varscan2
- AHCYL2 | c.1352T>C p.V451A | Missense Mutation (SNP) | VAF 73/103 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV61491352; called by muse, mutect2, varscan2
- AK5 | c.1287G>A p.M429I (on ENST00000354567 / NM_174858.3; = p.M403I on NM_012093.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as COSV60981900; called by muse, mutect2, varscan2
- AKR1B10 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV62056347; called by muse, mutect2, varscan2
- ALDH1A2 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51092101; called by muse, mutect2, varscan2
- AMPD3 | c.520C>T p.P174S (on ENST00000396553 / NM_001025389.2; = p.P183S on NM_000480.3) | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.21); catalogued as COSV67332253; called by muse, mutect2, varscan2
- ANKRD29 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV52427901; called by muse, mutect2, varscan2
- ANO2 | c.1420G>A p.E474K (on ENST00000356134 / NM_001278597.3; = p.E478K on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV59021118; called by muse, mutect2, varscan2
- AP1M2 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs368922983; called by mutect2, varscan2
- APOA4 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 106/179 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV63361186; called by muse, mutect2, varscan2
- APOL3 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV62579368; called by muse, mutect2, varscan2
- ARHGAP30 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV63519633; called by muse, mutect2, varscan2
- ARHGAP32 | c.4792C>T p.P1598S (on ENST00000310343 / NM_001378025.1; = p.P1249S on NM_014715.4) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59855985; called by muse, mutect2, varscan2
- ASNS | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 95/148 reads (64%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV51555996, COSV99445908; called by muse, mutect2, varscan2
- ATG4C | c.1012+1G>A p.X338_splice | Splice Site (SNP) | VAF 44/68 reads (65%) | catalogued as COSV58608567; called by muse, mutect2, varscan2
- ATP10A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV63512994; called by muse, mutect2, varscan2
- B3GALT1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1445278259, COSV59909890; called by muse, mutect2, varscan2
- BTN1A1 | c.1389G>A p.W463* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV55069706; called by muse, mutect2, varscan2
- C11orf53 | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54722703; called by muse, mutect2, varscan2
- C6 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs760521131, COSV54719009; called by muse, mutect2, varscan2
- C8orf58 | c.970G>A p.D324N (on ENST00000289989 / NM_001013842.3; = p.D316N on NM_173686.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV51516696; called by muse, mutect2, varscan2
- C9 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749534250, COSV54674594; called by muse, mutect2, varscan2
- CA1 | c.83A>C p.N28T | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV56280136; called by muse, mutect2, varscan2
- CACNA1E | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV62426034; called by muse, mutect2, varscan2
- CACNA1H | c.6263G>A p.G2088E | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.994); catalogued as COSV52358532; called by muse, mutect2, varscan2
- CALHM5 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV62068713; called by muse, mutect2, varscan2
- CALM2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs1312868284, COSV55400584; called by muse, mutect2, varscan2
- CALML4 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV61206281; called by muse, mutect2, varscan2
- CASP8 | c.368T>C p.L123P (on ENST00000432109 / NM_033355.3; = p.L155P on NM_001228.4) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV51849731, COSV51851868; called by muse, mutect2, varscan2
- CCDC33 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.385); catalogued as COSV51503652; called by muse, mutect2, varscan2
- CCDC87 | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 33/116 reads (28%) | catalogued as COSV59580488, COSV59580648; called by muse, mutect2, varscan2
- CCDC87 | c.1873G>T p.V625L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV59580652; called by muse, mutect2, varscan2
- CCKBR | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV58105778; called by muse, mutect2, varscan2
- CD163 | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV63137348; called by muse, mutect2, varscan2
- CDH17 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV50342061; called by muse, mutect2, varscan2
- CDH6 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV54078753; called by muse, mutect2, varscan2
- CDH9 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.345); catalogued as rs528896037, COSV50257556; called by muse, mutect2, varscan2
- CDRT4 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV56466645; called by muse, mutect2, varscan2
- CDYL2 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV73655021; called by muse, mutect2, varscan2
- CEACAM20 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 180/406 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57603360; called by muse, mutect2, varscan2
- CECR2 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773244829, COSV52845897, COSV52848577; called by muse, mutect2, varscan2
- CELA3B | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs140120229; called by muse, mutect2
- CEP126 | c.2671C>T p.H891Y | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs761399265, COSV54830890; called by muse, mutect2, varscan2
- CES3 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV57595111; called by muse, mutect2, varscan2
- CFAP53 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV68352906; called by muse, mutect2, varscan2
- CFTR | c.3140G>A p.G1047D | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs397508508, CS962501, COSV50106893; called by muse, mutect2, varscan2
- CHRNA5 | c.478T>G p.W160G | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55140717; called by muse, mutect2, varscan2
- CHST10 | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51807719; called by muse, mutect2, varscan2
- CLDN1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs537860492, COSV55044655; called by muse, mutect2, varscan2
- CLDND2 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52468225; called by muse, mutect2, varscan2
- CLEC4G | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.154); catalogued as COSV61004202; called by muse, mutect2, varscan2
- CMTR1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 142/233 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65091807; called by muse, mutect2, varscan2
- CMTR2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs147189785, COSV57603952; called by muse, mutect2, varscan2
- CNTLN | c.1159T>G p.L387V | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52097755; called by muse, mutect2, varscan2
- COBLL1 | c.1853C>A p.T618K (on ENST00000392717; = p.T580K on NM_014900.5) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52076646; called by muse, mutect2, varscan2
- COL11A2 | c.2617C>T p.P873S (on ENST00000341947 / NM_080680.3; = p.P766S on NM_080679.2) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV59502838; called by muse, mutect2
- COL4A4 | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV61631048; called by muse, mutect2, varscan2
- COL7A1 | c.4660G>A p.G1554R | Missense Mutation (SNP) | VAF 128/150 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879126840, COSV60403419; called by muse, mutect2, varscan2
- COL9A1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV57878018, COSV57893483; called by muse, mutect2, varscan2
- COX7B2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV57223335; called by muse, mutect2, varscan2
- CPAMD8 | c.3374C>T p.S1125F (on ENST00000651564; = p.S1078F on NM_015692.5) | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV71597415; called by muse, mutect2, varscan2
- CPT1A | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55761351; called by muse, mutect2, varscan2
- CPXM1 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV66046837; called by muse, mutect2, varscan2
- CRAMP1 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV51966335; called by muse, mutect2, varscan2
- CRNKL1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs749548472, COSV55648189; called by muse, mutect2, varscan2
- CSMD1 | c.9976G>A p.G3326R (on ENST00000520002; = p.G3325R on NM_033225.6) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59299327; called by muse, mutect2, varscan2
- CSMD1 | c.7394G>A p.R2465Q (on ENST00000520002; = p.R2464Q on NM_033225.6) | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs552956828, COSV59297016; called by muse, mutect2, varscan2
- CSMD1 | c.5702C>T p.A1901V (on ENST00000520002; = p.A1900V on NM_033225.6) | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59385502; called by muse, mutect2, varscan2
- CSMD1 | c.3605C>T p.T1202I (on ENST00000520002; = p.T1201I on NM_033225.6) | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1448668020, COSV59385537; called by muse, mutect2, varscan2
- CSMD1 | c.2010A>G p.I670M (on ENST00000520002; = p.I669M on NM_033225.6) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV59385573; called by muse, mutect2
- CSMD3 | c.1421-1G>A p.X474_splice (on ENST00000297405 / NM_001363185.1; = p.X370_splice on NM_052900.3) | Splice Site (SNP) | VAF 18/39 reads (46%) | catalogued as COSV52325105; called by muse, mutect2, varscan2
- CSN3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV59245070; called by muse, mutect2, varscan2
- CYLC1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as COSV61414494; called by muse, mutect2, varscan2
- CYP11A1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs918002510, COSV99165859; called by muse, mutect2, varscan2
- CYP2C9 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV53250701, COSV53252945; called by muse, mutect2, varscan2
- CYP4A11 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.519); catalogued as COSV60225760; called by muse, mutect2, varscan2
- CYP4A22 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 69/103 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs780190981, COSV53737797; called by muse, mutect2, varscan2
- DAND5 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV57684552; called by muse, mutect2, varscan2
- DAOA | c.45-1G>A p.X15_splice | Splice Site (SNP) | VAF 25/39 reads (64%) | catalogued as COSV61603669; called by muse, mutect2, varscan2
- DCC | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200830938; called by muse, mutect2, varscan2
- DCSTAMP | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs367714111; called by muse, mutect2, varscan2
- DDX60L | c.3359G>A p.G1120E | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1251519429, COSV52722299; called by muse, mutect2, varscan2
- DEF6 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57355459; called by muse, mutect2, varscan2
- DHRS3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV66108905; called by muse, mutect2, varscan2
- DHX37 | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs1250920736, COSV58133883; called by muse, mutect2, varscan2
- DMBT1 | c.5359C>T p.R1787* (on ENST00000338354 / NM_001377530.1; = p.R1030* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 91/205 reads (44%) | catalogued as rs201883302, COSV57540333; called by muse, mutect2, varscan2
- DMBT1 | c.5584G>A p.E1862K (on ENST00000338354 / NM_001377530.1; = p.E1105K on NM_004406.3) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs1045906158, COSV57534249; called by muse, mutect2, varscan2
- DNAH5 | c.13469G>A p.G4490E | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54201333; called by muse, mutect2, varscan2
- DNAH5 | c.10180G>A p.E3394K | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs770289921, COSV54204170; called by muse, mutect2, varscan2
- DNAH5 | c.5508G>A p.M1836I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV54222664, COSV54244587; called by muse, mutect2, varscan2
- DNAH5 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV54253239; called by muse, mutect2, varscan2
- DNAH7 | c.6551C>T p.S2184F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56766079; called by muse, varscan2
- DNAH8 | c.4115C>T p.P1372L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV59481671; called by muse, mutect2, varscan2
- DNAH8 | c.7618G>A p.E2540K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544337, COSV59480528; called by muse, mutect2
- DNAH9 | c.2830G>A p.G944S | Missense Mutation (SNP) | VAF 94/105 reads (90%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV52377754; called by muse, mutect2, varscan2
- DPPA4 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59512570; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DPYS | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1385455513, COSV60913837; called by muse, mutect2, varscan2
- DSCAM | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68036633; called by muse, mutect2, varscan2
- DSG3 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs377262567; called by muse, varscan2
- DYNLRB1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55964827; called by muse, mutect2, varscan2
- ELANE | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM002597, COSV55049656; called by muse, mutect2, varscan2
- ELAVL2 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs1197791365, COSV56371241; called by muse, mutect2, varscan2
- EPHA3 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 294/411 reads (72%) | SIFT tolerated (0.28); PolyPhen benign (0.054); catalogued as COSV60728211; called by muse, mutect2, varscan2
- ERP44 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52435306; called by muse, mutect2, varscan2
- F8 | c.4747C>T p.P1583S | Missense Mutation (SNP) | VAF 100/112 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV64278924; called by muse, varscan2
- FAM135B | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765801243, COSV52732747, COSV99417290; called by muse, mutect2
- FAM219A | c.379T>C p.S127P (on ENST00000445726; = p.S110P on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52622675; called by muse, mutect2
- FAM234B | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 44/97 reads (45%) | catalogued as rs764469409, COSV52192528; called by muse, mutect2, varscan2
- FAM83F | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 57/89 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60999473, COSV61001592; called by muse, mutect2, varscan2
- FBXO24 | c.1540G>A p.G514R (on ENST00000241071 / NM_033506.3; = p.G552R on NM_012172.5) | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as COSV53829754; called by muse, mutect2, varscan2
- FCRL3 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV63840681; called by muse, mutect2, varscan2
- FHL3 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.433); catalogued as COSV100885030; called by muse, mutect2, varscan2
- FHL3 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.022); catalogued as COSV100885031; called by muse, mutect2, varscan2
- FILIP1L | c.2594G>A p.W865* (on ENST00000354552 / NM_182909.3; = p.W625* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 70/139 reads (50%) | catalogued as COSV58776491; called by muse, mutect2, varscan2
- FLG | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.866); catalogued as COSV64249625; called by muse, mutect2, varscan2
- FLG2 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 125/191 reads (65%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV66168916, COSV66170068; called by muse, mutect2, varscan2
- FLT3 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54058304; called by muse, mutect2, varscan2
- FPR2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs866581731, COSV60672039; called by muse, mutect2, varscan2
- FSIP2 | c.17126C>T p.P5709L | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58100235; called by muse, mutect2, varscan2
- FSTL5 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV60231539; called by muse, mutect2, varscan2
- FUT3 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs267605641, COSV54608699; called by muse, mutect2, varscan2
- GABRG1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54950303; called by muse, mutect2, varscan2
- GALR1 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55319251; called by muse, varscan2
- GEM | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV52599252; called by muse, mutect2, varscan2
- GGT7 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755601936, COSV100321653; called by muse, mutect2, varscan2
- GIMAP4 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55431717; called by muse, mutect2, varscan2
- GNAZ | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 47/359 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1331938640, COSV50738087; called by muse, mutect2, varscan2
- GPRC6A | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59953604; called by muse, mutect2, varscan2
- GREB1 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99301995; called by muse, mutect2, varscan2
- GRK4 | c.1213G>A p.D405N (on ENST00000398052 / NM_182982.3; = p.D373N on NM_005307.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV61668317; called by muse, mutect2, varscan2
- GRM8 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 85/125 reads (68%) | SIFT tolerated (0.53); PolyPhen benign (0.168); catalogued as COSV58871044; called by muse, mutect2, varscan2
- GTPBP8 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV55607621; called by muse, mutect2, varscan2
- HECTD4 | c.7496G>A p.G2499E | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as COSV66400149; called by muse, mutect2, varscan2
- HMCN1 | c.4252C>A p.L1418I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.357); catalogued as COSV54943044; called by muse, mutect2, varscan2
- HNF1A | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 230/260 reads (88%) | catalogued as CM082824, COSV57463221; called by muse, mutect2
- HRC | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs542862175, COSV53258947; called by muse, mutect2, varscan2
- HTR3B | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as COSV52742476, COSV52742530; called by mutect2, varscan2
- IGHV3-53 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.286); catalogued as rs782414781; called by muse, mutect2, varscan2
- IGHV3-66 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.141); catalogued as rs782513119; called by muse, mutect2, varscan2
- IGSF10 | c.1475C>T p.T492I | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1243092430, COSV56791997; called by muse, mutect2, varscan2
- IKZF2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as COSV59577444; called by muse, mutect2, varscan2
- IP6K3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53392042; called by muse, mutect2, varscan2
- IPO8 | c.747T>A p.D249E | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.498); catalogued as COSV56246313; called by muse, mutect2, varscan2
- IRX6 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.59); PolyPhen benign (0.112); catalogued as COSV51862373; called by muse, mutect2, varscan2
- ITFG2 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57391166; called by muse, mutect2, varscan2
- ITGA1 | c.1576G>C p.V526L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV50899504; called by muse, mutect2, varscan2
- ITPRIP | c.1347G>A p.W449* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | catalogued as COSV53393264; called by muse, mutect2, varscan2
- IYD | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 65/77 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1246415361, COSV57604756; called by muse, varscan2
- JPH2 | c.1172C>G p.T391R | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65901656, COSV65905779; called by muse, mutect2, varscan2
- KCNB1 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 133/296 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.836); catalogued as rs770677266, COSV65566515; called by muse, mutect2, varscan2
- KCND2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV58573780; called by muse, mutect2, varscan2
- KCND3 | c.145C>G p.R49G | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.829); catalogued as COSV56183610, COSV56190019; called by muse, mutect2, varscan2
- KCNH7 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as COSV59805754; called by muse, mutect2, varscan2
- KCNK2 | c.593C>T p.T198I (on ENST00000444842 / NM_001017425.3; = p.T183I on NM_014217.4) | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV67210646; called by muse, mutect2, varscan2
- KCNV1 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.367); catalogued as rs1208332406, COSV52085557, COSV52087748; called by muse, mutect2, varscan2
- KHDRBS3 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV63422378; called by muse, mutect2, varscan2
- KIAA0319 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV65502003; called by muse, mutect2
- KIAA1109 | c.6773C>T p.P2258L | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52693018; called by muse, varscan2
- KIF15 | c.3167T>A p.I1056K | Missense Mutation (SNP) | VAF 60/67 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV58164881; called by muse, mutect2, varscan2
- KLHL14 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV63835612; called by muse, mutect2, varscan2
- KLHL22 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV61023019; called by muse, mutect2, varscan2
- KLK5 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs770159319, COSV60451665; called by muse, mutect2, varscan2
- KMT2B | c.3941G>A p.W1314* | Nonsense Mutation (SNP) | VAF 34/72 reads (47%) | catalogued as COSV55870087; called by muse, mutect2, varscan2
- KNDC1 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.546); catalogued as rs1467248094, COSV58846460; called by muse, varscan2
- KNDC1 | c.4796C>T p.S1599F | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV58846473; called by muse, mutect2, varscan2
- KRT9 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.841); catalogued as rs1392705236, COSV55855461; called by muse, mutect2
- KRTAP15-1 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV61878125; called by muse, mutect2, varscan2
- KRTAP4-12 | c.163T>G p.C55G | Missense Mutation (SNP) | VAF 56/61 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV67458337; called by muse, mutect2, varscan2
- KRTAP5-3 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV68791266; called by muse, mutect2, varscan2
- LAMC1 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV51180017; called by muse, mutect2, varscan2
- LCOR | c.3727C>G p.P1243A | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV53715139, COSV53718587; called by muse, mutect2, varscan2
- LILRA2 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV52197100; called by muse, varscan2
- LILRA2 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs267605669, COSV52197120; called by muse, varscan2
- LILRB4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as COSV99553390; called by muse, mutect2, varscan2
- LMAN1L | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV59003804; called by muse, mutect2, varscan2
- LMNA | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 169/248 reads (68%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs1205208123, COSV61544111; called by muse, mutect2, varscan2
- LMO7 | c.692C>T p.S231F (on ENST00000357063; = p.S246F on NM_005358.5) | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58549539; called by muse, mutect2, varscan2
- LONRF2 | c.997A>C p.K333Q | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.677); catalogued as COSV66542472; called by muse, mutect2, varscan2
- LRIT2 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60559272; called by muse, mutect2, varscan2
- LRRC14 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV52882911; called by muse, varscan2
- LRRC7 | c.1414G>A p.D472N (on ENST00000651989 / NM_001370785.2; = p.D439N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50633686; called by muse, mutect2, varscan2
- LRRC7 | c.1814G>A p.R605Q (on ENST00000651989 / NM_001370785.2; = p.R572Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs763720419, COSV50410760, COSV99065864; called by muse, mutect2, varscan2
- LTBP2 | c.4244C>T p.S1415F | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT tolerated (0.61); PolyPhen benign (0.068); catalogued as COSV56214355; called by muse, mutect2, varscan2
- MAGI1 | c.1430A>C p.K477T | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58345346; called by muse, varscan2
- MAN1A2 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV62976563; called by muse, mutect2, varscan2
- MAP4K1 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV67713332; called by muse, mutect2, varscan2
- MARCHF11 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1473774361, COSV60127649; called by muse, mutect2, varscan2
- MAST4 | c.4016C>T p.S1339F (on ENST00000403625 / NM_001164664.2; = p.S1150F on NM_015183.3) | Missense Mutation (SNP) | VAF 70/87 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214224110, COSV55142588; called by muse, mutect2, varscan2
- MBL2 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64758246; called by muse, mutect2, varscan2
- METTL25 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50262260; called by muse, mutect2, varscan2
- MGAM | c.5101C>G p.P1701A | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV72075900; called by muse, mutect2, varscan2
- MICU2 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 26/34 reads (76%) | catalogued as COSV66675554; called by muse, mutect2, varscan2
- MORC1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV51731611; called by muse, mutect2, varscan2
- MOV10L1 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 127/183 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763534299, COSV53176776; called by muse, mutect2
- MROH2B | c.2609G>A p.G870E | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.564); catalogued as COSV68186261; called by muse, mutect2, varscan2
- MSR1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV50536965; called by muse, mutect2, varscan2
- MTDH | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs779250302, COSV60346683; called by muse, mutect2, varscan2
- MTMR14 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 113/131 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV56007728; called by muse, mutect2, varscan2
- MUC16 | c.34295C>G p.T11432R | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101199983, COSV67495350; called by muse, mutect2
- MUC16 | c.14906C>T p.S4969F | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as COSV67495370; called by muse, mutect2, varscan2
- MUC16 | c.12032C>T p.S4011F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV67460203; called by muse, mutect2, varscan2
- MUC16 | c.10439G>A p.G3480E | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV67458733; called by muse, mutect2, varscan2
- MUC16 | c.8341G>A p.E2781K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67465001, COSV67495383; called by muse, mutect2, varscan2
- MUC17 | c.13432G>A p.E4478K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.4); catalogued as COSV60303942; called by muse, mutect2, varscan2
- MX1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV55821033; called by muse, mutect2, varscan2
- MYH15 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs767751424, COSV56312529, COSV56320049; called by muse, mutect2, varscan2
- MYL2 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 71/78 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV57407179; called by muse, mutect2, varscan2
- MYO18B | c.4793G>A p.R1598Q | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as rs370392393; called by muse, mutect2, varscan2
- MYRIP | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 21/24 reads (88%) | catalogued as rs1372128105, COSV56865698; called by muse, mutect2, varscan2
- NBPF1 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 58/645 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs754285176, COSV55329803; called by muse, varscan2
- NCOA2 | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs954106508, COSV51223310; called by muse, mutect2, varscan2
- NCOA6 | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.091); catalogued as COSV62864438, COSV62868209; called by muse, mutect2, varscan2
- NDN | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1312191153, COSV59361535; called by muse, mutect2
- NDST4 | c.1103T>G p.L368R | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52138084; called by muse, mutect2, varscan2
- NEDD4L | c.1276T>C p.S426P (on ENST00000400345 / NM_001144967.3; = p.S406P on NM_015277.6) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56853728; called by muse, mutect2
- NEK11 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63583959; called by muse, mutect2, varscan2
- NEURL1 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV63514400; called by muse, mutect2, varscan2
- NEUROD1 | c.709T>C p.S237P | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV54551241; called by muse, mutect2, varscan2
- NLRP8 | c.2382-1G>A p.X794_splice | Splice Site (SNP) | VAF 74/171 reads (43%) | catalogued as COSV52588823; called by muse, mutect2, varscan2
- NPC1L1 | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV56930534; called by muse, mutect2, varscan2
- NRIP3 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV58471312; called by muse, mutect2, varscan2
- NUP98 | c.1172T>C p.F391S | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61438878; called by muse, mutect2, varscan2
- NXPE1 | c.1171G>A p.E391K (on ENST00000424269; = p.E249K on NM_152315.5) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV52633505; called by muse, mutect2
- OBSCN | c.6857A>T p.K2286M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52831643; called by mutect2, varscan2
- OLFML3 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV57437075; called by muse, mutect2, varscan2
- OR13C8 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV58612511; called by muse, mutect2, varscan2
- OR4A15 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.223); catalogued as rs753415282, COSV100124011, COSV59033532; called by muse, mutect2, varscan2
- OR4K2 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 94/110 reads (85%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV53851741; called by muse, mutect2, varscan2
- OR4S2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56746238; called by muse, mutect2
- OR51I1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs867065145, COSV66507197, COSV66509228; called by muse, mutect2, varscan2
- OR51T1 | c.776G>A p.S259N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as rs764255917, COSV100434246; called by muse, mutect2, varscan2
- OR52A5 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV56616847; called by muse, mutect2, varscan2
- OR52E4 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV57626346; called by muse, mutect2, varscan2
- OR52H1 | c.197C>T p.S66F (on ENST00000322653; = p.S72F on NM_001005289.1) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1376357769, COSV59506286; called by muse, mutect2, varscan2
- OR52J3 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV66746527; called by muse, mutect2, varscan2
- OR52K1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV56904819; called by muse, mutect2, varscan2
- OR8D4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100361960, COSV58431603; called by muse, mutect2, varscan2
- OR8G1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.12); catalogued as COSV58383363; called by muse, mutect2, varscan2
- PAAF1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV60157388; called by muse, mutect2, varscan2
- PAK1 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53701632; called by muse, mutect2
- PARN | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV58363521, COSV58371302; called by muse, mutect2
- PBRM1 | c.3553C>T p.R1185* (on ENST00000296302 / NM_001366071.2; = p.R1160* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 28/30 reads (93%) | catalogued as COSV56264314; called by muse, mutect2, varscan2
- PCDH12 | c.3266C>A p.T1089K | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV51524912; called by muse, mutect2, varscan2
- PCDH15 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV57397545; called by muse, mutect2, varscan2
- PCDHB10 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.162); catalogued as rs782745367, COSV53375114, COSV53384031; called by muse, mutect2, varscan2
- PCDHGB2 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1404954356, COSV99528378; called by muse, mutect2, varscan2
- PCDHGB4 | c.1610C>T p.S537L | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs1300548775, COSV54037436; called by muse, mutect2, varscan2
- PCLO | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.012); catalogued as rs747593233, COSV61667530; called by muse, mutect2, varscan2
- PCM1 | c.4312C>T p.H1438Y | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV59588905; called by muse, mutect2, varscan2
- PCSK1 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 88/103 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs990328651, COSV60735780; called by muse, mutect2, varscan2
- PCSK2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV52743754; called by muse, mutect2, varscan2
- PDILT | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV56705371; called by muse, mutect2, varscan2
- PDS5B | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as COSV59734747; called by muse, mutect2, varscan2
- PHLDB2 | c.1676C>G p.P559R | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as COSV67316325; called by muse, mutect2, varscan2
- PM20D1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478129891, COSV65649734; called by muse, mutect2, varscan2
- POLRMT | c.1970C>T p.S657L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs760917021, COSV52114429; called by muse, mutect2, varscan2
- POM121L12 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV68692829; called by muse, mutect2, varscan2
- PPFIA2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61024990, COSV61045504; called by muse, mutect2, varscan2
- PRAMEF14 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 103/177 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs199937476; called by muse, mutect2, varscan2
- PRAMEF14 | c.292T>C p.W98R | Missense Mutation (SNP) | VAF 127/191 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as rs1308572099; called by muse, mutect2, varscan2
- PRB4 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.948); catalogued as COSV54396301, COSV54396460; called by muse, mutect2, varscan2
- PRKCA | c.529+1G>T p.X177_splice | Splice Site (SNP) | VAF 44/52 reads (85%) | catalogued as COSV52596133; called by muse, varscan2
- PRRG2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55871832; called by muse, mutect2, varscan2
- PRSS16 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs773835973, COSV57915867; called by muse, mutect2, varscan2
- PSG2 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV61546023; called by muse, mutect2, varscan2
- PSG8 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV60610014; called by muse, mutect2, varscan2
- PSMB2 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 85/117 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs754270458, COSV100951569; called by muse, mutect2, varscan2
- PTPN9 | c.1691A>G p.Y564C | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60726087; called by muse, mutect2, varscan2
- PTPRR | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 76/81 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs777721053, COSV51727722; called by muse, varscan2
- PTPRT | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62003196; called by muse, mutect2, varscan2
- PTRH1 | c.49A>C p.M17L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs752466662, COSV58854457; called by muse, mutect2
- PYHIN1 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV63724001; called by muse, varscan2
- RALGAPB | c.3658T>A p.S1220T | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.101); catalogued as COSV53444490; called by muse, mutect2, varscan2
- RAPGEF4 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 77/113 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51417317; called by muse, mutect2, varscan2
- RASGRP3 | c.1495G>A p.E499K (on ENST00000402538 / NM_001349975.2; = p.E498K on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV67825279; called by muse, mutect2, varscan2
- RASGRP4 | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.952); catalogued as COSV53094259, COSV53098162; called by muse, mutect2, varscan2
- RGS12 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs760422329, COSV60910457; called by muse, mutect2, varscan2
- RGS9 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV52229483; called by muse, mutect2, varscan2
- ROBO2 | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (0.35); PolyPhen benign (0.099); catalogued as COSV100166736, COSV59937523; called by muse, mutect2, varscan2
- RP1 | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs866140963, COSV55112404; called by muse, mutect2, varscan2
- RP1 | c.4486G>A p.E1496K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104377683, COSV55127307; called by muse, mutect2, varscan2
- RPS6KA2 | c.1897C>T p.L633F | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as rs1410648771, COSV55830778, COSV99692260; called by muse, mutect2, varscan2
- RSAD1 | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV51956743, COSV51957458; called by muse, varscan2
- S100G | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.994); catalogued as COSV63724423; called by muse, mutect2, varscan2
- SAC3D1 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV57248626; called by muse, varscan2
- SACS | c.5153C>T p.S1718F | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV66533704; called by muse, mutect2, varscan2
- SATB2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs769604856, COSV53492855; called by muse, varscan2
- SCN11A | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 76/92 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV56566193, COSV56581194; called by muse, mutect2, varscan2
- SCN11A | c.1603+1G>A p.X535_splice | Splice Site (SNP) | VAF 56/64 reads (88%) | catalogued as COSV56578709; called by muse, mutect2, varscan2
- SCN1A | c.5092G>A p.E1698K (on ENST00000303395 / NM_001202435.3; = p.E1687K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs548487014, COSV57667306; called by muse, mutect2, varscan2
- SCN1A | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV57688473; called by muse, mutect2, varscan2
- SCN9A | c.3927C>T p.V1309= (on ENST00000303354; = p.V1298= on NM_002977.3) | Splice Region (SNP) | VAF 14/59 reads (24%) | catalogued as rs751063265, COSV57625090; called by muse, mutect2, varscan2
- SCO1 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55136484; called by muse, mutect2, varscan2
- SCPEP1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV51855677; called by muse, mutect2, varscan2
- SDK2 | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV66197407; called by muse, mutect2, varscan2
- SEC14L1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV66722812; called by muse, mutect2, varscan2
- SERPINA7 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100568375, COSV59665943; called by muse, mutect2, varscan2
- SETMAR | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV62781528; called by muse, mutect2, varscan2
- SF3B6 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51981919, COSV99272715; called by muse, mutect2, varscan2
- SHANK2 | c.4799G>A p.R1600K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV53619720; called by muse, mutect2, varscan2
- SHE | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV59073288; called by muse, mutect2, varscan2
- SHISAL1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 171/251 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66988897; called by muse, mutect2, varscan2
- SI | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs1347233015, COSV52264647, COSV52301779; called by muse, mutect2, varscan2
- SIGLEC12 | c.1270C>T p.Q424* (on ENST00000291707 / NM_053003.4; = p.Q306* on NM_033329.2) | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV52462568, COSV99389522; called by mutect2, varscan2
- SLC12A5 | c.148C>T p.P50S (on ENST00000454036 / NM_001134771.2; = p.P27S on NM_020708.5) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs371579421, COSV54802239; called by muse, mutect2, varscan2
- SLC12A8 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58868299; called by muse, mutect2, varscan2
- SLC16A14 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751374739, COSV54618607; called by mutect2, varscan2
- SLC30A6 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as rs752028855, COSV50871920; called by muse, mutect2, varscan2
- SLC30A8 | c.989T>C p.V330A | Missense Mutation (SNP) | VAF 123/283 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs1377966068, COSV69976433; called by muse, varscan2
- SLC4A5 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697318; called by muse, mutect2, varscan2
- SLC4A7 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55403050; called by muse, mutect2, varscan2
- SLC6A3 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54369802; called by muse, mutect2, varscan2
- SLC9A4 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 34/54 reads (63%) | catalogued as COSV54829135, COSV54839520; called by muse, mutect2, varscan2
- SLCO1A2 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV56611028; called by muse, mutect2, varscan2
- SLCO1A2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs952098829, COSV56611051; called by muse, mutect2, varscan2
- SLCO4C1 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV60520423; called by muse, mutect2, varscan2
- SMG1 | c.8755G>A p.E2919K | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV67174902; called by muse, mutect2, varscan2
- SP140 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59448155; called by muse, mutect2, varscan2
- SPAST | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs758338312, COSV59517699; called by muse, mutect2, varscan2
- SPATA25 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV51945305; called by muse, mutect2, varscan2
- SPATA31A1 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as rs1378616728; called by mutect2, varscan2
- SPRY1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 78/97 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV59339291; called by muse, mutect2, varscan2
- SRPK1 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768481104, COSV60416395; called by mutect2, varscan2
- TACR3 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866456567, COSV59197957; called by muse, mutect2, varscan2
- TARS3 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV60109655; called by muse, mutect2, varscan2
- TAS2R7 | c.791A>C p.E264A | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV53688278, COSV53690811; called by muse, mutect2, varscan2
- TBC1D13 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 73/82 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV56354542; called by muse, mutect2, varscan2
- TBC1D9 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV71307306; called by muse, mutect2
- TCERG1L | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV64052580; called by muse, mutect2, varscan2
- TCHHL1 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 67/94 reads (71%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as COSV64287726; called by muse, mutect2, varscan2
- TCTN2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 67/72 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57635111; called by muse, mutect2, varscan2
- TDRKH | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 81/120 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV64316354, COSV64316820; called by muse, mutect2, varscan2
- TENM3 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs866724914, COSV69298496; called by muse, mutect2, varscan2
- TENM4 | c.7372A>T p.I2458F | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV53672499; called by muse, mutect2, varscan2
- TEX55 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV55212951; called by muse, mutect2, varscan2
- TG | c.5092C>T p.Q1698* | Nonsense Mutation (SNP) | VAF 45/114 reads (39%) | catalogued as COSV55094987; called by muse, mutect2, varscan2
- THSD7A | c.4609G>A p.E1537K | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV68472306; called by muse, mutect2, varscan2
- TMEM200A | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 59/63 reads (94%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51659845; called by muse, mutect2, varscan2
- TMEM255B | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs775273329, COSV64714990; called by muse, mutect2, varscan2
- TMEM39B | c.829T>C p.F277L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.067); catalogued as COSV60381378; called by muse, mutect2, varscan2
- TMPRSS7 | c.1844G>A p.G615E (on ENST00000452346; = p.G489E on NM_001042575.2) | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69982707; called by muse, mutect2, varscan2
- TNN | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs773607661, COSV53421649; called by muse, mutect2, varscan2
- TNRC6A | c.4837C>T p.R1613C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1050271217, COSV59370018; called by muse, mutect2, varscan2
- TOM1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs775808746, COSV65899815; called by muse, mutect2, varscan2
- TPTE | c.1300C>T p.Q434* (on ENST00000618007 / NM_199261.4; = p.Q416* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs771341118; called by muse, mutect2, varscan2
- TRERF1 | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs529112775, COSV61677199; called by muse, mutect2, varscan2
- TRIM15 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1187017742, COSV64990454; called by muse, mutect2, varscan2
- TRIM31 | c.960G>A p.W320* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV65060241; called by muse, mutect2
- TRIM71 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV67470761, COSV67472322; called by muse, mutect2, varscan2
- TRMT1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV53400804; called by muse, mutect2, varscan2
- TRMT10C | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.631); catalogued as COSV59305370, COSV59307038; called by muse, mutect2, varscan2
- TRMT9B | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192687145, COSV101501634; called by muse, mutect2, varscan2
- TRPM3 | c.2081C>T p.S694F (on ENST00000357533 / NM_001366142.2; = p.S537F on NM_020952.6) | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV62595518; called by muse, mutect2, varscan2
- TSPYL6 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV57820532; called by muse, mutect2, varscan2
- TTC39B | c.982T>G p.F328V | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52617046; called by muse, mutect2, varscan2
- TTLL1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 165/248 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV56737757; called by muse, mutect2, varscan2
- TTN | c.76295C>T p.P25432L (on ENST00000591111; = p.P18008L on NM_003319.4) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | PolyPhen probably damaging (0.999); catalogued as COSV100589267, COSV100609943; called by muse, mutect2, varscan2
- TTN | c.73981G>A p.E24661K (on ENST00000591111; = p.E17237K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/198 reads (18%) | PolyPhen benign (0.443); catalogued as COSV60360399; called by muse, mutect2, varscan2
- TTN | c.68479G>A p.E22827K (on ENST00000591111; = p.E15403K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | PolyPhen benign (0.015); catalogued as COSV60230648; called by muse, mutect2, varscan2
- TTN | c.64031G>A p.G21344E (on ENST00000591111; = p.G13920E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | PolyPhen probably damaging (1); catalogued as COSV60360461; called by muse, mutect2, varscan2
- TTN | c.41176G>A p.D13726N (on ENST00000591111; = p.D6302N on NM_003319.4) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | PolyPhen probably damaging (0.998); catalogued as rs1022025673, COSV60360489; called by muse, mutect2, varscan2
- TTN | c.23114G>A p.G7705E (on ENST00000591111; = p.G6778E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/124 reads (67%) | PolyPhen probably damaging (1); catalogued as COSV60360516; called by muse, mutect2, varscan2
- TTN | c.16043C>T p.P5348L (on ENST00000591111; = p.P4421L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | PolyPhen probably damaging (0.999); catalogued as rs771714891, COSV60225270, COSV60360530; called by muse, mutect2, varscan2
- TTN | c.14972G>A p.R4991Q (on ENST00000591111; = p.R4064Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | PolyPhen possibly damaging (0.69); catalogued as rs146847928, COSV60102722; called by muse, mutect2, varscan2
- TTN | c.9812C>T p.S3271F (on ENST00000591111; = p.S3225F on NM_003319.4) | Missense Mutation (SNP) | VAF 86/113 reads (76%) | PolyPhen benign (0.001); catalogued as rs867536098, COSV59891245, COSV60211933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.5202G>A p.M1734I (on ENST00000591111; = p.M1688I on NM_003319.4) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | PolyPhen probably damaging (0.961); catalogued as rs1561294571, COSV60360574; called by muse, mutect2
- TTN | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | PolyPhen probably damaging (0.987); catalogued as rs868569161, COSV59887692; called by muse, mutect2, varscan2
- TWNK | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV61328866; called by muse, mutect2, varscan2
- UBR4 | c.7430+2T>C p.X2477_splice | Splice Site (SNP) | VAF 16/82 reads (20%) | catalogued as COSV64399674; called by muse, mutect2
- UGGT1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs752208940, COSV52141857; called by muse, mutect2, varscan2
- UGT1A7 | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60852331; called by muse, mutect2, varscan2
- UGT2B15 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as COSV57735521; called by muse, mutect2, varscan2
- UGT3A1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs754987941, COSV57095662, COSV57098440; called by muse, mutect2
- UNC13C | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.023); catalogued as COSV99509916; called by muse, mutect2, varscan2
- UNC13C | c.1109C>A p.P370Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV99509918; called by muse, mutect2, varscan2
- UNC13C | c.4871G>A p.G1624E | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267604265, COSV52845412; called by muse, mutect2, varscan2
- USP29 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs866468815, COSV54237972; called by muse, mutect2, varscan2
- VWF | c.2968-1G>A p.X990_splice | Splice Site (SNP) | VAF 51/106 reads (48%) | catalogued as COSV54635148; called by muse, mutect2, varscan2
- XKR5 | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs760454991, COSV68398918; called by muse, varscan2
- YEATS4 | c.328A>G p.R110G | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56089857; called by muse, mutect2, varscan2
- ZAN | c.3173C>T p.S1058L | Missense Mutation (SNP) | VAF 206/330 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs199677862, COSV61807853; called by muse, mutect2, varscan2
- ZBTB49 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as rs1365901662, COSV61926173; called by muse, mutect2, varscan2
- ZCCHC4 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57183604; called by muse, mutect2, varscan2
- ZDBF2 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as COSV65630173; called by muse, mutect2, varscan2
- ZFAT | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as COSV64737482; called by muse, mutect2, varscan2
- ZIC1 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1302065329, COSV51558133; called by muse, mutect2, varscan2
- ZIM3 | c.1403G>A p.R468K | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV54140735, COSV54143087; called by muse, mutect2, varscan2
- ZNF341 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV61011318; called by muse, mutect2, varscan2
- ZNF445 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 55/71 reads (77%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV68539684; called by muse, mutect2, varscan2
- ZNF506 | c.809C>A p.A270E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV101475597; called by muse, mutect2, varscan2
- ZNF506 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV101475598; called by muse, mutect2, varscan2
- ZNF561 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV57179225; called by muse, mutect2, varscan2
- ZNF574 | c.1520A>G p.K507R | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV55907034; called by muse, mutect2, varscan2
- ZNF629 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV52700723; called by muse, mutect2, varscan2
- ZNF665 | c.457C>T p.R153C (on ENST00000600412; = p.R218C on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.151); catalogued as rs574751382, COSV67215170; called by muse, mutect2, varscan2
- ZNF71 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV60150337; called by muse, mutect2
- ZNF92 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60876187; called by muse, mutect2, varscan2
- ZP1 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV53927031; called by muse, mutect2, varscan2
- ZP4 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs747792401, COSV100850478; called by muse, mutect2, varscan2
- ZPBP | c.487+1G>T p.X163_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV50434906; called by muse, mutect2, varscan2
- ADAM32 | c.1849_1859del p.R617Gfs*17 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- ASPM | c.4102del p.L1368* | Frame Shift Del (DEL) | VAF 24/42 reads (57%) | called by mutect2, pindel, varscan2
- BTBD8 | c.729_738del p.Q244Lfs*6 | Frame Shift Del (DEL) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.993del p.F332Sfs*14 | Frame Shift Del (DEL) | VAF 45/83 reads (54%) | called by mutect2, pindel, varscan2
- FRG2C | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- IGLV1-50 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LIG4 | c.724_725del p.L242Ifs*5 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- LRRC32 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- MIR99AHG | n.664-1G>A | Splice Site (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- PLXNC1 | c.4316_4317dup p.G1440Tfs*6 | Frame Shift Ins (INS) | VAF 69/104 reads (66%) | called by mutect2, pindel, varscan2
- PTPN20 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | called by mutect2, varscan2
- TRAV1-2 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ADAMTS13 | c.1812C>T p.V604= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as rs782726724, COSV63023234; called by muse, mutect2, varscan2
- ADAMTS5 | c.1062C>T p.D354= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV53185657; called by muse, mutect2, varscan2
- ADCY10 | c.1914G>A p.R638= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV100896479; called by muse, mutect2, varscan2
- ADGRF3 | c.1353C>T p.A451= (on ENST00000311519 / NM_001145168.1; = p.A252= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1313008988, COSV61053502; called by muse, mutect2, varscan2
- ADGRF4 | c.1518C>T p.F506= | Silent (SNP) | VAF 44/169 reads (26%) | catalogued as COSV51957689; called by muse, mutect2, varscan2
- ADH7 | c.447C>G p.V149= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV52923293; called by muse, mutect2, varscan2
- AGRN | c.370C>T p.L124= | Silent (SNP) | VAF 83/111 reads (75%) | catalogued as COSV65072442, COSV65072832; called by muse, mutect2, varscan2
- AICDA | c.300G>A p.G100= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV57566402, COSV99984418; called by muse, mutect2, varscan2
- ALX4 | c.615C>T p.A205= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs777337755, COSV61328809; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANK1 | c.4569C>T p.S1523= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs749315744, COSV55896344; called by muse, mutect2
- ANKRD30A | c.1074T>G p.P358= (on ENST00000611781; = p.P302= on NM_052997.2) | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV64621815; called by muse, varscan2
- APLNR | c.963C>T p.T321= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs748455109, COSV57244121; called by muse, mutect2, varscan2
- APOB | c.4392G>A p.Q1464= | Silent (SNP) | VAF 388/572 reads (68%) | catalogued as COSV51947090; called by muse, mutect2, varscan2
- APOL2 | c.51G>A p.Q17= | Silent (SNP) | VAF 51/79 reads (65%) | catalogued as COSV50773218; called by muse, mutect2
- ASTN1 | c.1143G>A p.V381= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs373201552; called by muse, mutect2, varscan2
- ATP13A4 | c.3330C>T p.S1110= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV61327540; called by muse, varscan2
- ATP1A3 | c.489C>T p.S163= (on ENST00000545399 / NM_001256214.2; = p.S150= on NM_152296.5) | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV100132228, COSV57489581; called by muse, mutect2, varscan2
- ATP9A | c.1005C>T p.F335= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs1276952051, COSV58772247; called by muse, mutect2, varscan2
- BCCIP | c.537C>T p.L179= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV52943535; called by muse, mutect2, varscan2
- BRD4 | c.4047C>T p.F1349= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV54595481; called by muse, mutect2, varscan2
- C10orf71 | c.231G>A p.R77= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100109493; called by muse, mutect2, varscan2
- C16orf46 | c.327C>T p.S109= | Silent (SNP) | VAF 56/118 reads (47%) | catalogued as rs1300012076, COSV55153403; called by muse, mutect2, varscan2
- C2CD3 | c.4917C>T p.I1639= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV58101308; called by muse, mutect2, varscan2
- CACNA1E | c.4230C>T p.F1410= | Silent (SNP) | VAF 42/63 reads (67%) | catalogued as COSV62396516; called by muse, mutect2, varscan2
- CBFA2T3 | c.498C>T p.P166= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV51933181; called by muse, mutect2, varscan2
- CCDC127 | c.337T>C p.L113= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as rs758611075, COSV57258112; called by muse, mutect2, varscan2
- CCDC181 | c.1095G>A p.E365= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1234582370, COSV63156153, COSV63156501; called by muse, mutect2, varscan2
- CD33 | c.900C>T p.H300= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV51804934; called by muse, mutect2, varscan2
- CD36 | c.1329G>A p.L443= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as rs766238542, COSV59214583; called by muse, mutect2, varscan2
- CDSN | c.672C>T p.D224= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV52540066; called by muse, mutect2, varscan2
- CEP131 | c.2070C>T p.A690= (on ENST00000269392 / NM_001319228.2; = p.A687= on NM_014984.4) | Silent (SNP) | VAF 123/150 reads (82%) | catalogued as COSV53953347; called by muse, mutect2, varscan2
- CES3 | c.357C>T p.S119= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as rs773828115, COSV57592812; called by muse, mutect2
- CHAT | c.642C>T p.S214= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs758544604, COSV60333457; called by muse, mutect2, varscan2
- CHAT | c.1212A>C p.A404= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV60333480; called by muse, mutect2, varscan2
- CLPX | c.1830C>T p.S610= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as rs1181662666, COSV55646918; called by muse, mutect2, varscan2
- COL14A1 | c.3090G>A p.K1030= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs753257419, COSV52869297; called by muse, mutect2, varscan2
- COL22A1 | c.3651C>T p.I1217= | Silent (SNP) | VAF 77/192 reads (40%) | catalogued as rs1350601689, COSV57361699; called by muse, mutect2, varscan2
- CRB1 | c.3789G>A p.K1263= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV66333982; called by muse, mutect2, varscan2
- CRYBG2 | c.1383G>A p.R461= | Silent (SNP) | VAF 49/60 reads (82%) | catalogued as rs755415157, COSV57490393; called by muse, mutect2, varscan2
- CSMD2 | c.807C>T p.T269= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs752412612, COSV53883668; called by muse, mutect2, varscan2
- CTNND2 | c.193C>T p.L65= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV58929568; called by muse, mutect2, varscan2
- CYP11A1 | c.1398G>A p.R466= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV99165860; called by muse, mutect2, varscan2
- CYP2C19 | c.978G>A p.E326= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV64909530; called by muse, mutect2, varscan2
- CYP4F12 | c.1050C>T p.Y350= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV61176826; called by muse, mutect2, varscan2
- DAPK2 | c.909G>A p.L303= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99976946; called by muse, mutect2, varscan2
- DBH | c.414G>A p.R138= | Silent (SNP) | VAF 23/24 reads (96%) | catalogued as COSV55042411; called by muse, mutect2, varscan2
- DCAF8L1 | c.414G>A p.A138= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as rs375651987, COSV71595332; called by muse, mutect2, varscan2
- DCSTAMP | c.891C>T p.F297= | Silent (SNP) | VAF 84/179 reads (47%) | catalogued as COSV52580220; called by muse, mutect2, varscan2
- DDX20 | c.2229C>T p.S743= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as COSV63779626; called by muse, mutect2, varscan2
- DEFB116 | c.231T>C p.S77= | Silent (SNP) | VAF 77/203 reads (38%) | catalogued as rs1260691356, COSV68722483; called by muse, mutect2, varscan2
- DGKI | c.2055G>A p.R685= | Silent (SNP) | VAF 121/178 reads (68%) | catalogued as COSV55976986, COSV99932185; called by muse, mutect2, varscan2
- DHX36 | c.657A>G p.L219= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as COSV57677406; called by muse, mutect2, varscan2
- DMBT1 | c.1851C>T p.V617= | Silent (SNP) | VAF 65/171 reads (38%) | catalogued as COSV57563238; called by muse, mutect2, varscan2
- DNAH3 | c.7336C>T p.L2446= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV54553214; called by muse, mutect2, varscan2
- DOC2A | c.672C>T p.S224= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV58752903; called by muse, mutect2, varscan2
- DOCK4 | c.2400G>A p.V800= | Silent (SNP) | VAF 43/65 reads (66%) | catalogued as COSV70243381; called by muse, mutect2, varscan2
- DSC1 | c.285C>T p.F95= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs770260276, COSV57145590; called by muse, mutect2, varscan2
- DUOX2 | c.3669C>T p.H1223= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV66534766; called by muse, mutect2, varscan2
- DYSF | c.289C>T p.L97= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as COSV50599156; called by muse, mutect2, varscan2
- EBF2 | c.216G>A p.A72= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs771303415, COSV68780669; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.456C>T p.I152= | Silent (SNP) | VAF 46/51 reads (90%) | catalogued as rs766613478, COSV55744447; called by muse, mutect2, varscan2
- EPHA6 | c.1617G>A p.L539= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV67594461; called by mutect2, varscan2
- EPHB2 | c.2409C>T p.F803= (on ENST00000400191 / NM_001309193.2; = p.F804= on NM_004442.7) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs201751121; called by mutect2, varscan2
- EPHB2 | c.2652C>T p.I884= (on ENST00000400191 / NM_001309193.2; = p.I885= on NM_004442.7) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV101007261, COSV65866953; called by muse, mutect2
- ERICH3 | c.1068G>A p.G356= | Silent (SNP) | VAF 38/50 reads (76%) | catalogued as COSV58611295; called by muse, mutect2, varscan2
- EVPL | c.5004G>A p.R1668= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as COSV56916378; called by muse, mutect2, varscan2
- FCGBP | c.12213C>T p.I4071= | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- FER | c.2160G>A p.K720= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as COSV55306602; called by muse, mutect2, varscan2
- FGA | c.507G>A p.L169= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV57401278; called by muse, mutect2
- FLCN | c.1521C>G p.L507= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV53263523; called by muse, mutect2, varscan2
- FLNB | c.768A>G p.K256= | Silent (SNP) | VAF 32/37 reads (86%) | catalogued as COSV55896252; called by muse, mutect2, varscan2
- FMO2 | c.465C>T p.I155= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs1426702949, COSV52950490; called by muse, mutect2, varscan2
- FNDC7 | c.882G>A p.T294= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as rs773585731, COSV54756557; called by muse, mutect2, varscan2
- FOXD4 | c.426C>T p.R142= | Silent (SNP) | VAF 77/102 reads (75%) | catalogued as rs768039898, COSV58703080; called by muse, mutect2
- GALNT11 | c.186C>T p.G62= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as rs952994524, COSV57428808; called by muse, mutect2, varscan2
- GALNT17 | c.1528C>T p.L510= | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as COSV100356425, COSV61192762; called by muse, mutect2, varscan2
- GGT7 | c.1341C>T p.L447= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV60540181; called by muse, mutect2, varscan2
- GIMAP7 | c.435C>T p.F145= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV57960720; called by muse, mutect2, varscan2
- GPR157 | c.426G>A p.L142= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV66234395; called by muse, mutect2, varscan2
- GRM7 | c.1545C>T p.V515= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV63144025; called by muse, mutect2, varscan2
- HAL | c.159C>T p.F53= | Silent (SNP) | VAF 52/57 reads (91%) | catalogued as COSV54120397; called by muse, mutect2, varscan2
- HERC2 | c.13962C>T p.A4654= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99870033; called by muse, mutect2, varscan2
- HSD3B1 | c.441G>A p.L147= | Silent (SNP) | VAF 62/93 reads (67%) | catalogued as COSV52492304; called by muse, mutect2, varscan2
- HSPG2 | c.8895C>T p.L2965= | Silent (SNP) | VAF 50/68 reads (74%) | catalogued as COSV65934088; called by muse, mutect2, varscan2
- HYDIN | c.12519G>A p.K4173= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs267604615, COSV66642472; called by muse, mutect2, varscan2
- IGHV6-1 | c.135C>T p.S45= | Silent (SNP) | VAF 34/43 reads (79%) | catalogued as rs377508313; called by muse, mutect2, varscan2
- IGSF1 | c.3075C>T p.I1025= | Silent (SNP) | VAF 30/33 reads (91%) | catalogued as COSV63840501; called by muse, mutect2, varscan2
- KCNA1 | c.15T>G p.S5= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV66838743; called by muse, mutect2, varscan2
- KCNU1 | c.2646G>A p.G882= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV67759984; called by muse, mutect2, varscan2
- KIAA0319 | c.738G>A p.E246= | Silent (SNP) | VAF 57/86 reads (66%) | catalogued as COSV65501989; called by muse, mutect2, varscan2
- KIF26B | c.3417C>T p.S1139= | Silent (SNP) | VAF 51/78 reads (65%) | catalogued as COSV63652695; called by muse, mutect2, varscan2
- KIF5C | c.816G>A p.G272= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as COSV68482909; called by muse, mutect2, varscan2
- KRT18 | c.681G>A p.Q227= | Silent (SNP) | VAF 52/54 reads (96%) | catalogued as COSV66316751; called by muse, mutect2, varscan2
- LILRB4 | c.168G>A p.R56= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV99553388; called by muse, mutect2, varscan2
- LPA | c.1014G>A p.G338= | Silent (SNP) | VAF 22/243 reads (9%) | catalogued as COSV100305825, COSV100307494; called by muse, mutect2, varscan2
- LRCH4 | c.345C>T p.A115= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV53829736; called by muse, mutect2, varscan2
- LRFN2 | c.1701G>A p.K567= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV57834898; called by muse, mutect2, varscan2
- LRP1B | c.3417C>T p.P1139= | Silent (SNP) | VAF 51/73 reads (70%) | catalogued as COSV67253433, COSV67276654; called by muse, mutect2, varscan2
- LRP8 | c.2271C>T p.T757= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs764704853, COSV100035909; called by muse, mutect2, varscan2
- LRRTM3 | c.1641G>A p.T547= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs544274000, COSV63670030; called by muse, mutect2, varscan2
- MED12L | c.2472C>T p.L824= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV56398351; called by muse, mutect2, varscan2
- MGAM | c.2184C>T p.F728= | Silent (SNP) | VAF 145/497 reads (29%) | catalogued as rs782186263, COSV72075899; called by muse, mutect2, varscan2
- MUC16 | c.30651C>T p.A10217= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV67488034; called by muse, mutect2, varscan2
- MUC16 | c.25002C>T p.T8334= | Silent (SNP) | VAF 59/125 reads (47%) | catalogued as rs747470439, COSV67495358; called by muse, mutect2, varscan2
- MUC16 | c.17763G>A p.V5921= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV67478058; called by muse, mutect2, varscan2
- MX2 | c.639C>T p.I213= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV58098920; called by muse, mutect2, varscan2
- MYH2 | c.4473G>A p.K1491= | Silent (SNP) | VAF 40/46 reads (87%) | catalogued as COSV55448844, COSV99821248; called by muse, mutect2, varscan2
- NCAM1 | c.1500G>A p.L500= (on ENST00000316851 / NM_181351.5; = p.L490= on NM_000615.7) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV57524503; called by muse, mutect2, varscan2
- NEB | c.12543G>A p.R4181= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs1430827486, COSV51461097; called by muse, mutect2, varscan2
- NLRP8 | c.1053C>T p.L351= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs267605703, COSV52585055; called by muse, mutect2, varscan2
- NNMT | c.231C>T p.S77= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as COSV100248951, COSV55475100; called by muse, mutect2, varscan2
- NPAP1 | c.1011G>A p.P337= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs142610787, COSV61505934; called by muse, mutect2, varscan2
- NPAS4 | c.669A>G p.K223= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV60652893; called by muse, mutect2, varscan2
- NPHS2 | c.780G>A p.V260= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV62636666; called by muse, mutect2, varscan2
- NUMB | c.534G>A p.V178= (on ENST00000355058; = p.V167= on NM_003744.5) | Silent (SNP) | VAF 28/34 reads (82%) | catalogued as rs200599673; called by muse, mutect2, varscan2
- OAS3 | c.2685C>T p.A895= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV57449545; called by muse, mutect2, varscan2
- OR13C9 | c.357C>T p.A119= | Silent (SNP) | VAF 64/74 reads (86%) | catalogued as COSV52243837; called by muse, mutect2, varscan2
- OR1B1 | c.903G>A p.K301= | Silent (SNP) | VAF 26/31 reads (84%) | catalogued as COSV59172438; called by muse, mutect2, varscan2
- OR2A25 | c.57C>T p.G19= | Silent (SNP) | VAF 102/153 reads (67%) | catalogued as rs747472836, COSV68717723; called by muse, varscan2
- OR2A25 | c.132C>T p.I44= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV68717726; called by muse, varscan2
- OR2C3 | c.66C>T p.P22= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV63576388; called by muse, mutect2, varscan2
- OR2M2 | c.549C>T p.S183= | Silent (SNP) | VAF 28/178 reads (16%) | catalogued as COSV62897915; called by muse, mutect2, varscan2
- OR4K15 | c.393C>T p.F131= (on ENST00000305051; = p.F107= on NM_001005486.1) | Silent (SNP) | VAF 70/81 reads (86%) | catalogued as COSV59300306; called by muse, mutect2, varscan2
- OR5T3 | c.169C>T p.L57= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV57382635; called by muse, mutect2, varscan2
- OTUD7A | c.393C>T p.S131= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV61043634; called by muse, mutect2, varscan2
- P2RY13 | c.216C>T p.I72= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV56398339; called by muse, mutect2, varscan2
- PCCA | c.1470C>T p.I490= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV66199033; called by muse, mutect2, varscan2
- PCDH15 | c.5046G>A p.R1682= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV64678689; called by muse, mutect2
- PCDH15 | c.4056G>A p.L1352= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs200926530, COSV100213344; called by muse, mutect2, varscan2
- PCDHGB2 | c.1695C>T p.P565= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as rs760465689, COSV99528381, COSV99549024; called by muse, mutect2, varscan2
- PCLO | c.7725C>T p.S2575= | Silent (SNP) | VAF 165/258 reads (64%) | catalogued as COSV61667516; called by muse, mutect2, varscan2
- PDCD6 | c.24C>T p.P8= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as rs781514333, COSV53781142; called by muse, mutect2, varscan2
- PDILT | c.285G>A p.G95= | Silent (SNP) | VAF 164/408 reads (40%) | catalogued as COSV56705380; called by muse, mutect2, varscan2
- PDXK | c.441C>T p.I147= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs771848735, COSV52365171; called by muse, mutect2, varscan2
- PHF21B | c.327C>A p.P109= | Silent (SNP) | VAF 27/234 reads (12%) | catalogued as COSV57562581; called by muse, mutect2, varscan2
- PLA2G4D | c.1668G>A p.K556= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV51823996; called by muse, mutect2, varscan2
- PLEKHA7 | c.511C>T p.L171= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV63051259; called by muse, mutect2, varscan2
- PNPLA5 | c.843C>T p.G281= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV53376374; called by muse, mutect2, varscan2
- POM121L12 | c.420G>A p.G140= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as COSV68694468; called by muse, mutect2, varscan2
- PROC | c.957C>T p.C319= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV52168498; called by muse, mutect2, varscan2
- PROX1 | c.1575G>A p.R525= | Silent (SNP) | VAF 61/85 reads (72%) | catalogued as rs1044548051, COSV54783914; called by muse, mutect2, varscan2
- PRSS36 | c.2295C>T p.T765= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs1216188923, COSV51639860; called by muse, mutect2, varscan2
- PYGB | c.432C>T p.F144= | Silent (SNP) | VAF 83/170 reads (49%) | catalogued as COSV53818704; called by muse, mutect2, varscan2
- RERGL | c.426A>T p.A142= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV57463738; called by muse, mutect2, varscan2
- RSPH9 | c.462C>T p.I154= | Silent (SNP) | VAF 107/164 reads (65%) | catalogued as rs1383143751, COSV64665876; called by muse, mutect2, varscan2
- RYR2 | c.13824G>A p.R4608= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV63715097; called by muse, mutect2, varscan2
- SASH1 | c.1014C>T p.S338= | Silent (SNP) | VAF 43/53 reads (81%) | catalogued as COSV66566120; called by muse, mutect2, varscan2
- SAT2 | c.336G>A p.K112= | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as COSV52647910; called by muse, mutect2, varscan2
- SCN10A | c.3075C>T p.I1025= | Silent (SNP) | VAF 25/29 reads (86%) | catalogued as COSV71862710; called by muse, mutect2, varscan2
- SCN11A | c.1080C>T p.S360= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as COSV56578715; called by muse, mutect2, varscan2
- SDR42E1 | c.321C>T p.L107= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as COSV61095116; called by muse, mutect2, varscan2
- SEMA5B | c.243C>T p.L81= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV52108515; called by muse, mutect2, varscan2
- SETX | c.6501C>T p.F2167= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as COSV56395034; called by muse, mutect2, varscan2
- SF1 | c.321G>A p.E107= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV57117570; called by muse, mutect2, varscan2
- SIAH3 | c.390C>T p.I130= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as rs1268303883, COSV68553351; called by muse, mutect2, varscan2
- SIGLEC5 | c.1413G>A p.G471= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV55784135; called by muse, mutect2, varscan2
- SLC10A2 | c.690A>G p.G230= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV55361824; called by muse, mutect2, varscan2
- SLC12A8 | c.1374C>T p.F458= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV58871089; called by muse, mutect2, varscan2
- SLC16A4 | c.1437C>G p.A479= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs777078429, COSV63917402; called by mutect2, varscan2
- SLC4A5 | c.633C>T p.V211= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100697319; called by muse, mutect2, varscan2
- SNX1 | c.291C>T p.S97= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV56040117, COSV56040242; called by muse, mutect2, varscan2
- SPTA1 | c.5514G>A p.K1838= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as COSV63759821; called by muse, varscan2
- SSRP1 | c.996C>T p.F332= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV53481725; called by muse, mutect2, varscan2
- SUPT5H | c.2535C>T p.T845= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as rs1265965152, COSV63242266; called by muse, varscan2
- SYNPO2 | c.3051G>A p.T1017= | Silent (SNP) | VAF 25/30 reads (83%) | catalogued as rs770008859, COSV61111922, COSV61117696; called by muse, varscan2
- TCF4 | c.975G>A p.G325= | Silent (SNP) | VAF 73/274 reads (27%) | catalogued as rs770354308, COSV61906632; called by muse, mutect2, varscan2
- THSD7B | c.1437C>T p.I479= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs751892896, COSV55682244, COSV55729033; called by muse, mutect2, varscan2
- TIGD3 | c.351C>T p.F117= | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as rs1397580021, COSV52891454; called by muse, mutect2, varscan2
- TMPRSS7 | c.1629C>T p.D543= (on ENST00000452346; = p.D417= on NM_001042575.2) | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV69982697; called by muse, mutect2, varscan2
- TNFSF10 | c.336C>T p.P112= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV53844612; called by muse, mutect2
- TNFSF9 | c.642C>T p.V214= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV55539049; called by muse, mutect2, varscan2
- TNS1 | c.1890C>T p.P630= | Silent (SNP) | VAF 42/63 reads (67%) | catalogued as rs1414474267, COSV50771876; called by muse, mutect2, varscan2
- TPTE2 | c.252C>T p.V84= (on ENST00000400230 / NM_199254.2; = p.V47= on NM_130785.3) | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as rs1227215787, COSV55028623; called by muse, mutect2, varscan2
- TRIM55 | c.144G>A p.R48= | Silent (SNP) | VAF 78/200 reads (39%) | catalogued as COSV52551034; called by muse, mutect2, varscan2
- TUBGCP4 | c.25C>T p.L9= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV53021624; called by muse, mutect2, varscan2
- UBE3C | c.396G>A p.L132= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV61955714; called by muse, mutect2, varscan2
- USP9Y | c.2676G>A p.R892= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV59100665; called by muse, mutect2
- WDR7 | c.414C>T p.I138= | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as COSV54363699; called by muse, mutect2, varscan2
- XKR4 | c.1776A>G p.E592= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as COSV59340150; called by muse, mutect2, varscan2
- ZBED1 | c.1851C>T p.A617= | Silent (SNP) | VAF 91/204 reads (45%) | catalogued as COSV58139106; called by muse, mutect2, varscan2
- ZFPM2 | c.2412G>A p.T804= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV65872612, COSV65873438; called by muse, mutect2, varscan2
- ZG16B | c.387C>T p.F129= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV66526037; called by muse, mutect2, varscan2
- ZIC1 | c.912C>T p.C304= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV51558122; called by muse, mutect2, varscan2
- ZNF208 | c.2304G>A p.K768= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV101236627, COSV68102134; called by muse, mutect2, varscan2
- ZNF366 | c.1110C>T p.C370= | Silent (SNP) | VAF 26/28 reads (93%) | catalogued as rs201820869, COSV59219210; called by muse, mutect2, varscan2
- ZNF493 | c.453C>T p.Y151= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV100828738, COSV62752449; called by muse, mutect2, varscan2
- ZNF501 | c.111T>C p.L37= | Silent (SNP) | VAF 29/31 reads (94%) | catalogued as COSV68516735; called by muse, mutect2, varscan2
- ZNF518A | c.783C>T p.P261= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs782816677, COSV100283443, COSV60153511; called by muse, mutect2, varscan2
- ZNF536 | c.1449G>A p.G483= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs1326307838, COSV62823784; called by muse, mutect2, varscan2
- ZNF875 | c.546C>T p.L182= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV60994007; called by muse, mutect2, varscan2
- ABCA3 | c.-87C>T | 5'UTR (SNP) | VAF 9/18 reads (50%) | catalogued as rs1284010029, COSV100067897; called by muse, mutect2, varscan2
- AC004080.3 | c.11-4548C>T | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99385199; called by muse, mutect2, varscan2
- C8orf31 | n.596G>A | RNA (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- CA6 | c.259+2047G>A | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101077293; called by muse, varscan2
- CDCA7 | c.147+614C>T | Intron (SNP) | VAF 39/52 reads (75%) | catalogued as COSV60720444; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37167193 G>A | 3'Flank (SNP) | VAF 15/37 reads (41%) | catalogued as COSV57075187; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22434C>T | Intron (SNP) | VAF 29/51 reads (57%) | catalogued as COSV101050730; called by muse, mutect2, varscan2
- KHK | c.210-242C>T | Intron (SNP) | VAF 19/85 reads (22%) | catalogued as COSV53157407; called by muse, mutect2, varscan2
- KIR3DX1 | n.658C>T | RNA (SNP) | VAF 29/73 reads (40%) | catalogued as COSV55596949, COSV55597343; called by muse, mutect2, varscan2
- KLK8 | c.71-18C>T | Intron (SNP) | VAF 46/84 reads (55%) | catalogued as rs759957133, COSV51594763; called by muse, mutect2, varscan2
- MIR487B | n.30C>T | RNA (SNP) | VAF 35/40 reads (88%) | catalogued as rs753329635; called by muse, mutect2, varscan2
- MYL3 | chr3:46833055 G>A | 3'Flank (SNP) | VAF 37/46 reads (80%) | catalogued as COSV70134124; called by muse, mutect2, varscan2
- PABPC4 | c.972+337C>T | Intron (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100790831; called by muse, mutect2, varscan2
- PRR12 | c.51+257C>T | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as COSV55871837; called by muse, mutect2, varscan2
- R3HDML | chr20:44355823 C>T | 3'Flank (SNP) | VAF 107/266 reads (40%) | catalogued as COSV53836890; called by muse, mutect2, varscan2
- R3HDML | chr20:44355824 C>T | 3'Flank (SNP) | VAF 110/272 reads (40%) | catalogued as COSV99406970; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163846 G>A | 5'Flank (SNP) | VAF 34/220 reads (15%) | catalogued as rs765642305; called by muse, varscan2
- SH2D6 | n.583C>T | RNA (SNP) | VAF 19/25 reads (76%) | catalogued as COSV61064125; called by muse, mutect2, varscan2
- TAF8 | chr6:42048648 C>T | 5'Flank (SNP) | VAF 10/17 reads (59%) | catalogued as COSV65897202; called by muse, mutect2, varscan2
- TTN | c.10361-4195G>A | Intron (SNP) | VAF 17/94 reads (18%) | catalogued as COSV60120288; called by muse, mutect2, varscan2
- TTN | c.10361-4626C>T | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100589270; called by muse, mutect2, varscan2
- TTN | c.10360+4546C>T | Intron (SNP) | VAF 70/107 reads (65%) | catalogued as rs558862374, COSV100589271; called by muse, mutect2, varscan2
- ZNF783 | c.802+3078C>T | Intron (SNP) | VAF 28/99 reads (28%) | catalogued as rs746201321, COSV65186358; called by muse, mutect2, varscan2
